Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A6U8, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A6U8-01A (Primary Tumor).

Neuropathology

Commentary:

Histology and morphology correspond to diffuse astrocytoma WHO grade II.

Diagnosis:

Diffuse astrocytoma WHO grade II

CXFP ICD 6-3
Astrocytoma, grade II 9400/3
path
Astrocytoma, diffuse 9400/3
Site: Brain, supratentorial NOS
C71.0
7/25/13

untranslated original report
is housed at the BCR.

Criteria	hw 7/9/13	Yes	No

Source: NCI Genomic Data Commons file 0cf18f96-9b1e-46c1-84cb-c135de42e490 (TCGA-S9-A6U8.6999D0D0-E961-478C-8935-71765A100941.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).